Gene-level copy-number profile of specimen HCM-CSHL-0654-C26-85M from HCMI case HCM-CSHL-0654-C26, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Primary diagnosis: Carcinoma, NOS; Tissue or organ of origin: Unknown primary site; Tumor grade: G3; Age at diagnosis: 70.6 years (25,800 days).
Specimen HCM-CSHL-0654-C26-85M: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 7.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file f0d1e5a4-1b6f-4279-a2f5-61c282add871.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-CSHL-0654-C26-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,736 have no estimate.
https://portal.gdc.cancer.gov/files/826bf6ac-3217-4c0f-a680-e2c9c55224d8

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 1,054; copy number 2: 25,504; copy number 3: 28,909; copy number 4: 3,381; copy number 5: 19; copy number 6: 1; copy number 15: 3; copy number 92: 1; copy number 93: 3; copy number 97: 1; copy number 106: 4; copy number 108: 1; copy number 113: 6.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 19 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:124,044,395–124,171,522, 1 gene, copy number 93 (within-gene range 3–93): FER1L6-AS2.
- chr11:34,742,906–35,620,865, 15 genes, copy number 92–113: AL359999.1, APIP, PDHX, MIR1343, AL356215.1, CD44, CD44-AS1, AL133330.1, SLC1A2, SLC1A2-AS1, AC090625.1, AC090625.2, PAMR1, AL135934.1, FJX1.
- chr13:109,478,739–109,786,583, 3 genes, copy number 15 (within-gene range 3–15): AL163541.1, LINC00676, IRS2.

Autosomal genes at a single copy (total copy number 1): 232. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
